CCDI case PBCDWD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/04954054-96aa-446a-8308-87d6cc897604

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.9 years (1,436 days).

Biospecimens (3 samples)
- Sample 0DR1XB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR1YL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR20E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
